Somatic mutation profile of tumor specimen TCGA-SN-A6IS-01A (aliquot TCGA-SN-A6IS-01A-11D-A435-10) from TCGA case TCGA-SN-A6IS, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 26.3 years (9,618 days).
Specimen TCGA-SN-A6IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1364b89-216c-49c5-a653-d76655a63806.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SN-A6IS-10A (Blood Derived Normal), aliquot TCGA-SN-A6IS-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8819e6d4-07e2-498c-b972-99d3f742a525

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Frame Shift Del 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.4742G>A p.G1581D (on ENST00000614293; = p.G1551D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs767253473; called by muse, mutect2, varscan2
- HTT | c.8741G>T p.R2914L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as rs752690276, COSV61863794, COSV61865635; called by mutect2, varscan2
- MYH9 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53383943; called by muse, mutect2, varscan2
- REEP6 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52014110, COSV99278494; called by mutect2, varscan2
- AMH | c.152_153del p.Q51Rfs*29 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- CCNK | c.38C>G p.T13S | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGB1 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ROCK2 | c.1724_1725del p.S575* | Frame Shift Del (DEL) | VAF 28/145 reads (19%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.3810_3814del p.N1270Kfs*2 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- ZNF789 | c.395_396del p.C132* | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | called by pindel, varscan2
- GMEB2 | c.1218G>A p.P406= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs368204390; called by muse, mutect2, varscan2
- ZNF777 | c.81C>T p.L27= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs1347546304; called by muse, mutect2, varscan2
